Surgical pathology report (de-identified scan), TCGA case TCGA-30-1891, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1891-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED]
Type: Surgical Pathology
Pathology Report
Accessioned On: [REDACTED]

Report Status: Final

OMENTUM BIOPSY

DIAGNOSIS:

SPECIMEN LABELED "OMENTAL TUMOR" (including FSA):
PAPILLARY SEROUS ADENOCARCINOMA (17 cm).

SPECIMEN LABELED "OMENTECTOMY TUMOR SPECIMEN":
PAPILLARY SEROUS ADENOCARCINOMA (28 cm).

SPECIMEN LABELED "TUMOR FROM MESENTERIC COLON (TRANSVERSE)":
PAPILLARY SEROUS ADENOCARCINOMA (19.5 cm).

SPECIMEN LABELED "TUMOR EDGE OF STOMACH":
PAPILLARY SEROUS ADENOCARCINOMA (5.8 cm).

SPECIMEN LABELED "TUMOR RIGHT COLONIC GUTTER":
PAPILLARY SEROUS ADENOCARCINOMA (5.8 cm).

SPECIMEN LABELED "LEFT ADNEXA":
PAPILLARY SEROUS ADENOCARCINOMA (grade 2 of 3), with involvement of both ovaries (up to 3.5 cm) and peritoneal metastases (up to 28 cm). See NOTE.
Lymphovascular invasion is not present.
The left fallopian tube and uterine serosa are involved by tumor.
There is invasion of the right ovary and surface involvement of both ovaries.

SPECIMEN LABELED "RIGHT ADNEXA":
PAPILLARY SEROUS ADENOCARCINOMA (see above).

SPECIMEN LABELED "TUMOR CUL DE SAC":
PAPILLARY SEROUS ADENOCARCINOMA (4 cm).

SPECIMEN LABELED "UTERUS AND CERVIX":

Cervix:

Squamous metaplasia.

Endometrium:

Inactive endometrium.

Myometrium:

Leiomyoma.

Serosa:

PAPILLARY SEROUS ADENOCARCINOMA with extension into paracervical tissue.

Note: The distribution of tumor suggests a peritoneal or ovarian surface primary.

CLINICAL DATA:

History: year old with ascites, omental cake and pelvic mass.

Clinical Diagnosis: Pelvic mass.

TISSUE SUBMITTED: 1. Omental tumor (FS)
2. Rectus muscle biopsy (FS)
3. Omentectomy tumor specimen
4. Tumor from mesenteric colon (transverse)
5. Tumor edge of stomach
6. Tumor right colonic gutter
7. Left adnexa
8. Right adnexa
9. Tumor cul de sac
10. Uterus with cervix
O.R. CONSULTATION:

[page 2 of 3]
SPECIMEN LABELED "OMENTAL TUMOR" (FSA):

Papillary serous carcinoma.

GROSS DESCRIPTION: by [REDACTED], M.D.

The specimen is received fresh in ten parts, each labeled with the patient's name and unit number.

Part one, "omental tumor", consists of a 17.2 x 6.5 x 1.1 cm fragment of omental diffusely involved by tan, firm tumor that infiltrates the fibroadipose tissue. Representative sections of the tumor are submitted as FSA and for special studies. Representative sections are submitted.

Micro sections:

Micro 1: frozen section A remnant, 1 frag, RSS.

Micro 2: omental cake, 1 frag, RSS.

Part two, "rectus biopsy biopsy", consists of a 0.8 x 0.6 x 0.2 cm fragment of skeletal muscle that is entirely submitted for special studies.

Part three, "omentectomy tumor specimen", consists of a 28 x 8 x 3 cm fragment of omentum that is diffusely involved by a tan firm tumor that infiltrates fibroadipose tissue. Representative sections are submitted.

Micro 3: omentectomy, 2 frags, RSS.

Part four, "tumor from mesenteric colon transverse", consists of a 19.5 x 5 x 3.2 cm fragment of tan, papillary, firm tumor infiltrating fibroadipose tissue. There are focal areas of necrosis (up to 0.8 cm). Representative sections are submitted.

Micro 4: tumor with necrosis, 1 frag, RSS.

Micro 5: tumor, 1 frag, RSS.

Part five, "tumor edge of stomach", consists of a 5.8 x 5.8 x 3.5 cm fragment of tan/papillary tumor that diffusely infiltrates fibroadipose tissue. Representative sections are submitted.

Micro 6: tumor from edge of stomach, 1 frag, RSS.

Part six, "tumor right colonic gutter", consists of a 5.8 x 5.9 x 2.0 cm fragment of fibroadipose tissue, diffusely infiltrate by a tan, papillary tumor that is focally cystic. The cyst contents are clear to yellow with a predominately serous, partially gelatinous texture. Representative sections are submitted.

Micro 7: tumor right colonic gutter, 1 frag, RSS.

Part seven, "left adnexa", consists of a 4.2 x 0.7 cm fimbriated fallopian tube with serosal tumor deposits and adhesion, attached to a 3.5 x 2.7 x 1.7 cm partially disrupted ovary with tumor diffusely involving the surface of the ovary. The fallopian tube appears to be penetrated by tumor.

Micro 8: ovary, 2 frags, RSS.

Micro 9: fallopian tube, 3 frags, RSS.

Micro 10: fallopian tube and ovary, 1 frag, RSS.

Part eight, "right adnexa", consists of a 7.2 x 0.8 cm interruption, fimbriated fallopian tube, with a 2.5 x 1.5 x 0.9 cm ovary whose surface is involved by tumor. Tumor extends up to involve the serosa of the fallopian tube and diffusely involves the area of interruption in the fallopian tube. Representative sections are submitted.

Micro 11: fallopian tube, 3 frags, RSS.

Micro 12: ovary and fallopian tube with intervening tumor, 1 frag, RSS.

Micro 13: ovary, 2 frags, RSS.

Part nine, "tumor cul de sac", consists of multiple fragments of tan/yellow firm tissue, consistent with tumor infiltrating fibroadipose tissue (4 x 3 x 1 cm in aggregate). Representative sections are submitted.

Printed:

[page 3 of 3]
Micro 14: tumor cul de sac, 2 frags, RSS.

Part ten, "uterus with cervix", consists of a 79 gm hysterectomy specimen (8.5 x 5.3 x 2.5 cm in overall dimension). The exocervix has a tan, smooth mucosa and measures 3.5 x 2.8 cm, with a 0.5 cm slit-like os, leading to a 2.2 cm endocervical canal. There are heaped up areas of mucosa on the anterior surface of the endocervix. The endometrial cavity measures 2.5 x 2.5 cm and the endometrium measures 0.1 cm in thickness with no gross evident lesions. There is a 1.2 cm intramural leiomyoma. The serosal surface is focally hemorrhagic and has possible tumor deposits, up to 0.5 cm, particularly on the anterior side. Representative sections are submitted.

Micro 15: posterior cervix, 1 frag, RSS.

Micro 16: anterior cervix, 1 frag, RSS.

Micro 17: lower uterine segment, 1 frag, RSS.

Micro 18: posterior endometrium with fibroid, 1 frag, RSS.

Micro 19: anterior endometrium, 1 frag, RSS.

Micro 20: suspicious areas on serosa, 2 frags, RSS.

Reports to: _____

SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: TISSUE FOR SPECIAL STUDIES ONLY

ADDITIONAL SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE MASS OR SIMPLE EXCISION

ADDITIONAL SPECIMEN TYPE: SOFT TISSUE BIOPSY

ADDITIONAL SPECIMEN TYPE: UTERUS WITH OR WITHOUT TUBES & OVARIES, NEOPLASTIC

ADDITIONAL SPECIMEN TYPE: PERITONEUM BIOPSY

Source: NCI Genomic Data Commons file 931c74b7-fc15-49df-8f64-6d5ebc457158 (TCGA-30-1891.F2E0C289-3ED3-4876-8BFA-A447AB1DBB2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).